Somatic mutation profile of tumor specimen TCGA-DM-A1D9-01A (aliquot TCGA-DM-A1D9-01A-11D-A152-10) from TCGA case TCGA-DM-A1D9, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage IIA; Age at diagnosis: 67.1 years (24,514 days).
Specimen TCGA-DM-A1D9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 503f48dd-fd53-4f0b-a54b-48b237d8d816.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DM-A1D9-10A (Blood Derived Normal), aliquot TCGA-DM-A1D9-10A-01D-A152-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/42c0fbea-2f38-40c7-89ae-f8aef1b67263

The open-access MAF lists 147 somatic variants for this specimen: 106 protein-altering or splice-affecting, 36 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 86, Silent 36, Frame Shift Ins 5, In Frame Del 4, Nonsense Mutation 4, Splice Site 3, RNA 2, Frame Shift Del 2, Translation Start Site 1, 5'Flank 1, In Frame Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 85/214 reads (40%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 66/140 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 20/34 reads (59%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCC8 | c.2125A>G p.T709A | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as COSV56850118; called by muse, mutect2, varscan2
- ADAM19 | c.859C>T p.R287C | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1368514508, COSV57429337; called by muse, mutect2, varscan2
- AKAP5 | c.853C>G p.L285V | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.034); catalogued as COSV57742356; called by muse, mutect2
- ALMS1 | c.11432G>A p.S3811N | Missense Mutation (SNP) | VAF 70/201 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.17); catalogued as rs1177181684, COSV52509338; called by muse, mutect2, varscan2
- ANKRD13C | c.1456G>A p.V486I | Missense Mutation (SNP) | VAF 73/185 reads (39%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.557); catalogued as rs1449411575, COSV99257543; called by muse, mutect2, varscan2
- ARMC6 | c.608G>A p.R203H (on ENST00000392336; = p.R178H on NM_033415.4) | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.073); catalogued as rs373198003; called by muse, mutect2, varscan2
- ARMC9 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 38/113 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63019195, COSV63020816; called by muse, mutect2, varscan2
- ATF6 | c.158A>T p.Y53F | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV63407364; called by muse, mutect2, varscan2
- B3GNT3 | c.919G>A p.E307K | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.122); catalogued as rs1044284298, COSV57953178; called by muse, mutect2, varscan2
- BRCA2 | c.2959_2961del p.N987del | In Frame Del (DEL) | VAF 20/126 reads (16%) | catalogued as rs730881603; called by pindel, varscan2
- BRD4 | c.1957G>T p.E653* | Nonsense Mutation (SNP) | VAF 12/77 reads (16%) | catalogued as COSV54586053; called by muse, mutect2, varscan2
- BTAF1 | c.3238C>G p.Q1080E | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT tolerated (0.39); PolyPhen benign (0.074); catalogued as rs1367883501, COSV56433666; called by muse, mutect2, varscan2
- CACNG7 | c.209G>T p.G70V | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as COSV55813125, COSV55814330; called by muse, mutect2, varscan2
- CADM2 | c.550G>T p.V184F (on ENST00000407528 / NM_001167674.2; = p.V186F on NM_153184.4) | Missense Mutation (SNP) | VAF 99/249 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV67372862; called by muse, mutect2, varscan2
- CC2D1A | c.2125+1G>T p.X709_splice | Splice Site (SNP) | VAF 12/24 reads (50%) | catalogued as COSV58783133; called by muse, mutect2, varscan2
- CCDC150 | c.1277T>G p.L426R | Missense Mutation (SNP) | VAF 30/328 reads (9%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.495); catalogued as COSV55874162; called by muse, mutect2
- CCDC7 | c.305A>G p.Y102C | Missense Mutation (SNP) | VAF 91/224 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs541761405, COSV99511867; called by muse, varscan2
- CELSR1 | c.8203A>T p.T2735S | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.647); catalogued as COSV53089698; called by muse, varscan2
- CEP78 | c.205C>T p.P69S | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated (0.5); PolyPhen benign (0.015); catalogued as COSV52847165; called by muse, mutect2, varscan2
- CLK4 | c.1224G>C p.K408N | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.576); catalogued as COSV60318678; called by muse, mutect2, varscan2
- COL4A5 | c.1107A>C p.E369D | Missense Mutation (SNP) | VAF 23/282 reads (8%) | SIFT tolerated (0.54); PolyPhen benign (0.012); catalogued as COSV60361173; called by muse, mutect2
- COL6A6 | c.3322G>T p.V1108F | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV62024459; called by muse, mutect2, varscan2
- COPS5 | c.710T>A p.L237* | Nonsense Mutation (SNP) | VAF 11/38 reads (29%) | catalogued as COSV63474416; called by muse, mutect2, varscan2
- CPXCR1 | c.629A>T p.E210V | Missense Mutation (SNP) | VAF 33/188 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV52162132; called by muse, mutect2, varscan2
- DNAH11 | c.11338G>A p.D3780N | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100180572; called by muse, mutect2, varscan2
- DOCK11 | c.2686C>A p.L896I | Missense Mutation (SNP) | VAF 70/368 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV52238507; called by muse, mutect2, varscan2
- DOK7 | c.437C>G p.P146R | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CD1212493, CM102920, COSV100403551, COSV60771977; called by muse, mutect2, varscan2
- EFEMP1 | c.605C>A p.P202H | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as COSV62615998, COSV62618216; called by muse, mutect2, varscan2
- ESPNL | c.13C>T p.R5W | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as rs1327789319, COSV54541268; called by muse, mutect2, varscan2
- ESRP2 | c.467_469del p.F156del | In Frame Del (DEL) | VAF 10/56 reads (18%) | catalogued as rs771845554; called by pindel, varscan2
- FANCA | c.140C>T p.A47V | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.965); catalogued as COSV66881544; called by muse, mutect2, varscan2
- FAT3 | c.6922C>A p.Q2308K | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.069); catalogued as COSV53107155; called by muse, mutect2, varscan2
- FBXO9 | c.894G>T p.R298S | Missense Mutation (SNP) | VAF 91/241 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55055704; called by muse, mutect2, varscan2
- FKBP6 | c.241C>G p.P81A | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99334271; called by muse, mutect2
- FRYL | c.6122G>A p.R2041Q | Missense Mutation (SNP) | VAF 70/162 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as rs764312788, COSV51940848, COSV51952315; called by muse, mutect2, varscan2
- GABBR2 | c.786A>T p.K262N | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.486); catalogued as COSV52302742; called by muse, mutect2, varscan2
- GHSR | c.183C>G p.N61K | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53838937; called by muse, mutect2, varscan2
- GIMAP8 | c.1010C>G p.T337S | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.47); PolyPhen benign (0.056); catalogued as COSV100217681; called by muse, mutect2, varscan2
- GNAT3 | c.386G>A p.R129Q | Missense Mutation (SNP) | VAF 58/148 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.025); catalogued as rs768900454, COSV68068684; called by muse, mutect2, varscan2
- GREB1 | c.2944A>T p.I982F | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV52186612; called by muse, mutect2, varscan2
- H2AC14 | c.193G>C p.E65Q | Missense Mutation (SNP) | VAF 44/156 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.999); catalogued as COSV60797644; called by muse, mutect2, varscan2
- HARS2 | c.1267C>T p.Q423* | Nonsense Mutation (SNP) | VAF 55/141 reads (39%) | catalogued as COSV51226978; called by muse, mutect2, varscan2
- HERC2 | c.7361C>T p.S2454L | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.276); catalogued as rs879255382, COSV55350151; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HINT2 | c.296G>A p.R99Q | Missense Mutation (SNP) | VAF 48/114 reads (42%) | SIFT tolerated (0.85); PolyPhen benign (0.058); catalogued as rs751219625, COSV52414128; called by muse, mutect2, varscan2
- HYDIN | c.10529T>A p.L3510H | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV101158212; called by muse, mutect2, varscan2
- ITIH6 | c.2206C>G p.L736V | Missense Mutation (SNP) | VAF 54/160 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.05); catalogued as COSV99513870; called by muse, mutect2, varscan2
- KCNMB1 | c.436G>A p.V146I | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.636); catalogued as rs369035536; called by muse, mutect2, varscan2
- KDR | c.2372G>A p.R791Q | Missense Mutation (SNP) | VAF 53/146 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.3); catalogued as rs758102038, COSV55757419, COSV55763403; called by muse, mutect2, varscan2
- LCE2D | c.49C>T p.P17S | Missense Mutation (SNP) | VAF 42/130 reads (32%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0.011); catalogued as rs537040687, COSV64228979; called by muse, mutect2, varscan2
- LMBRD1 | c.11C>G p.S4C | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.068); catalogued as COSV65341623; called by muse, mutect2
- LRRC4C | c.539G>T p.G180V | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99539456; called by muse, mutect2, varscan2
- MAD1L1 | c.1861G>C p.V621L | Missense Mutation (SNP) | VAF 45/127 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as rs1562502326, COSV56233823; called by muse, mutect2, varscan2
- MAP3K13 | c.2242G>A p.A748T | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as COSV53988432; called by muse, mutect2, varscan2
- MCF2 | c.19C>T p.R7W | Missense Mutation (SNP) | VAF 71/162 reads (44%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.64); catalogued as rs186682047, COSV58484316; called by muse, mutect2, varscan2
- MEX3C | c.1956_1957insGTTACG p.V651_T652dup | In Frame Ins (INS) | VAF 22/33 reads (67%) | catalogued as COSV68529840; called by mutect2, varscan2
- MME | c.1113G>A p.M371I | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.031); catalogued as COSV64707264; called by muse, mutect2, varscan2
- MTREX | c.2447A>G p.E816G | Missense Mutation (SNP) | VAF 16/270 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.044); catalogued as COSV100044462; called by muse, mutect2
- MYCT1 | c.5G>A p.R2Q | Missense Mutation (SNP) | VAF 73/204 reads (36%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs773225210, COSV65891270; called by muse, mutect2, varscan2
- MYF6 | c.667G>A p.V223M | Missense Mutation (SNP) | VAF 49/127 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57351550; called by muse, mutect2, varscan2
- MYO1G | c.1147C>T p.R383W | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.935); catalogued as rs748813866, COSV51854462; called by muse, mutect2, varscan2
- MYOM3 | c.509C>T p.T170M | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.916); catalogued as rs372001214; called by muse, mutect2, varscan2
- NTRK3 | c.1372C>T p.R458* | Nonsense Mutation (SNP) | VAF 57/80 reads (71%) | catalogued as COSV58120958; called by muse, mutect2, varscan2
- OCRL | c.1672G>A p.E558K | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV63980846; called by muse, mutect2, varscan2
- P3H2 | c.2035-2del p.X679_splice | Splice Site (DEL) | VAF 50/154 reads (32%) | catalogued as COSV60021334; called by mutect2, pindel, varscan2
- PADI1 | c.1855C>A p.L619M | Missense Mutation (SNP) | VAF 41/104 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV64934521; called by muse, mutect2, varscan2
- PCDHB3 | c.1189G>A p.V397I | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.007); catalogued as COSV50572048; called by muse, mutect2, varscan2
- PCDHGA8 | c.19C>T p.R7C | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.006); catalogued as COSV53943265; called by muse, mutect2
- PCNT | c.6719C>G p.P2240R | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV100855994; called by muse, mutect2, varscan2
- PDGFRA | c.2735G>C p.G912A | Missense Mutation (SNP) | VAF 73/208 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV57267752; called by muse, mutect2, varscan2
- PFKFB4 | c.443A>C p.N148T | Missense Mutation (SNP) | VAF 79/192 reads (41%) | PolyPhen benign (0.145); catalogued as COSV51680799; called by muse, mutect2, varscan2
- PGM5 | c.1427C>T p.T476M | Missense Mutation (SNP) | VAF 40/101 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.336); catalogued as rs200812025; called by muse, mutect2, varscan2
- PLCB1 | c.171A>T p.Q57H | Missense Mutation (SNP) | VAF 75/214 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as COSV62049478; called by muse, mutect2, varscan2
- PLEKHA4 | c.2186C>T p.S729L | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.168); catalogued as rs905978670, COSV54362934; called by muse, mutect2, varscan2
- PLEKHG5 | c.1876G>T p.G626W (on ENST00000400915 / NM_001042663.3; = p.G589W on NM_020631.6) | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61068368; called by muse, mutect2, varscan2
- PLXNB3 | c.590C>T p.S197L | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.544); catalogued as rs782765277, COSV62797219; called by muse, mutect2, varscan2
- POTEE | c.2591C>T p.P864L | Missense Mutation (SNP) | VAF 43/141 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.625); catalogued as COSV58230272; called by muse, mutect2, varscan2
- PUM2 | c.97G>A p.D33N | Missense Mutation (SNP) | VAF 62/153 reads (41%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.99); catalogued as COSV57579653; called by muse, mutect2, varscan2
- RGS20 | c.487G>A p.A163T | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.001); catalogued as COSV99392476; called by muse, mutect2, varscan2
- RPTOR | c.3757G>C p.V1253L | Missense Mutation (SNP) | VAF 24/37 reads (65%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as rs762913188, COSV60808245; called by muse, mutect2, varscan2
- SH3RF3 | c.1135C>T p.R379C | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as rs753317886, COSV58685651, COSV58688989; called by muse, mutect2, varscan2
- SH3YL1 | c.605A>T p.D202V | Missense Mutation (SNP) | VAF 18/230 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.857); catalogued as COSV62156298; called by muse, mutect2
- SLC24A2 | c.600C>A p.H200Q | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.781); catalogued as COSV53864395; called by muse, varscan2
- SLC9C1 | c.3349del p.T1117Hfs*4 | Frame Shift Del (DEL) | VAF 40/123 reads (33%) | catalogued as COSV59887981; called by mutect2, pindel, varscan2
- SMAD4 | c.1447+1G>C p.X483_splice | Splice Site (SNP) | VAF 94/137 reads (69%) | catalogued as CS064452, COSV100748195, COSV61684548, COSV61688290; called by muse, mutect2, varscan2
- SNX17 | c.1217G>A p.R406H | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as rs763365098, COSV52007714; called by muse, mutect2, varscan2
- SUPT5H | c.527A>T p.D176V | Missense Mutation (SNP) | VAF 112/209 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63239527; called by muse, mutect2, varscan2
- TMEM218 | c.116C>T p.S39F | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as COSV54445117, COSV99692576; called by muse, mutect2, varscan2
- TMEM218 | c.115T>A p.S39T | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.987); catalogued as COSV54445125; called by muse, mutect2
- TNS3 | c.3067G>A p.G1023S | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as COSV60790696; called by muse, mutect2, varscan2
- TXK | c.1004A>T p.Q335L | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as COSV51914778; called by muse, mutect2, varscan2
- VCAN | c.6065T>A p.V2022D | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.23); catalogued as COSV54104536; called by muse, mutect2, varscan2
- WDR72 | c.2941C>G p.Q981E | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV64746275, COSV64753946; called by muse, mutect2
- ZFR | c.1916A>C p.Q639P | Missense Mutation (SNP) | VAF 21/247 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as COSV54052844; called by muse, mutect2
- ZNF547 | c.290A>G p.K97R | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.968); catalogued as COSV56580381; called by muse, mutect2, varscan2
- AMER1 | c.1228del p.W410Gfs*12 | Frame Shift Del (DEL) | VAF 40/134 reads (30%) | called by mutect2, pindel, varscan2
- APC | c.4731dup p.C1578Mfs*13 | Frame Shift Ins (INS) | VAF 48/91 reads (53%) | called by mutect2, pindel, varscan2
- CEPT1 | c.553dup p.C185Lfs*28 | Frame Shift Ins (INS) | VAF 121/305 reads (40%) | called by mutect2, varscan2
- KMT2B | c.2386_2388del p.L796del | In Frame Del (DEL) | VAF 8/57 reads (14%) | called by pindel, varscan2
- NCAPD3 | c.3427dup p.S1143Ffs*5 | Frame Shift Ins (INS) | VAF 18/58 reads (31%) | called by mutect2, pindel, varscan2
- PPP1R21 | c.344_346del p.K115del | In Frame Del (DEL) | VAF 90/250 reads (36%) | called by pindel, varscan2
- SLCO1B1 | c.1504T>G p.Y502D | Missense Mutation (SNP) | VAF 10/173 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.005); called by muse, mutect2
- ZBTB24 | c.1656dup p.Q553Sfs*10 | Frame Shift Ins (INS) | VAF 11/109 reads (10%) | called by mutect2, pindel, varscan2
- ZFP36L2 | c.410dup p.Q138Afs*336 | Frame Shift Ins (INS) | VAF 28/95 reads (29%) | called by pindel, varscan2
- AC127029.3 | c.666C>T p.Y222= | Silent (SNP) | VAF 50/64 reads (78%) | catalogued as rs370785603; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALMS1 | c.11433C>T p.S3811= | Silent (SNP) | VAF 68/198 reads (34%) | catalogued as COSV52509345; called by muse, mutect2, varscan2
- ASIC1 | c.1008C>T p.Y336= | Silent (SNP) | VAF 48/109 reads (44%) | catalogued as rs750767632, COSV57317788; called by muse, mutect2, varscan2
- CDH11 | c.1788C>T p.D596= | Silent (SNP) | VAF 23/63 reads (37%) | catalogued as rs1185141824, COSV51760992; called by muse, mutect2, varscan2
- CEP170B | c.2841G>A p.P947= (on ENST00000453495; = p.P876= on NM_015005.3) | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as rs766329767, COSV69024411; called by muse, mutect2, varscan2
- CHIC1 | c.75G>A p.A25= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as COSV100998260; called by mutect2, varscan2
- CHODL | c.588A>T p.T196= | Silent (SNP) | VAF 20/42 reads (48%) | catalogued as rs774331601, COSV54732624; called by muse, mutect2, varscan2
- CTBP1 | c.1257C>T p.H419= | Silent (SNP) | VAF 42/103 reads (41%) | catalogued as rs1453823824, COSV52073900; called by muse, mutect2, varscan2
- CYP26A1 | c.942T>A p.T314= | Silent (SNP) | VAF 39/57 reads (68%) | catalogued as COSV56418021; called by muse, mutect2, varscan2
- EWSR1 | c.1860G>C p.G620= | Silent (SNP) | VAF 32/47 reads (68%) | catalogued as rs962201986, COSV58423439, COSV58423623; called by muse, mutect2, varscan2
- FIBCD1 | c.903G>A p.A301= | Silent (SNP) | VAF 22/53 reads (42%) | catalogued as rs750732451, COSV53393359; called by muse, mutect2, varscan2
- GAS2L2 | c.915C>A p.T305= | Silent (SNP) | VAF 44/67 reads (66%) | called by muse, mutect2, varscan2
- HDAC9 | c.1752G>A p.A584= | Silent (SNP) | VAF 29/77 reads (38%) | catalogued as COSV67772711; called by muse, mutect2, varscan2
- INO80D | c.330C>T p.A110= | Silent (SNP) | VAF 57/140 reads (41%) | catalogued as COSV68958846; called by muse, mutect2, varscan2
- KALRN | c.8673C>T p.N2891= (on ENST00000360013 / NM_001024660.4; = p.N1194= on NM_007064.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 46/102 reads (45%) | catalogued as rs758592148, COSV52255832; called by muse, mutect2, varscan2
- KDM7A | c.936A>T p.A312= | Silent (SNP) | VAF 41/83 reads (49%) | catalogued as COSV50091324; called by muse, mutect2, varscan2
- LMOD1 | c.1332T>C p.N444= | Silent (SNP) | VAF 38/136 reads (28%) | catalogued as COSV66172629; called by muse, mutect2, varscan2
- MAGI2 | c.411G>A p.T137= | Silent (SNP) | VAF 35/77 reads (45%) | catalogued as rs149568072, COSV100835566; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ODC1 | c.889T>C p.L297= | Silent (SNP) | VAF 34/84 reads (40%) | catalogued as COSV52172257; called by muse, mutect2, varscan2
- OR10A7 | c.708G>A p.K236= | Silent (SNP) | VAF 43/87 reads (49%) | catalogued as rs762564739, COSV58278365; called by muse, mutect2, varscan2
- OR5H2 | c.627C>A p.G209= | Silent (SNP) | VAF 157/412 reads (38%) | catalogued as rs1292132406, COSV62350719; called by muse, mutect2, varscan2
- PCDHA11 | c.2175G>T p.T725= | Silent (SNP) | VAF 51/104 reads (49%) | catalogued as rs782014542, COSV56498950, COSV56540936; called by muse, mutect2, varscan2
- PFKFB3 | c.510C>A p.I170= | Silent (SNP) | VAF 15/39 reads (38%) | catalogued as COSV57988640; called by muse, mutect2, varscan2
- PLEKHG4B | c.3813C>A p.A1271= (on ENST00000283426; = p.A1627= on NM_052909.5) | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as COSV52047104; called by muse, mutect2, varscan2
- RHOBTB3 | c.87G>C p.L29= | Silent (SNP) | VAF 17/103 reads (17%) | catalogued as COSV66102012; called by muse, mutect2, varscan2
- RP1L1 | c.966C>T p.S322= | Silent (SNP) | VAF 21/28 reads (75%) | catalogued as rs865791745, COSV66754878; called by muse, mutect2, varscan2
- RRNAD1 | c.1387C>T p.L463= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as rs752782468, COSV63928958; called by muse, mutect2, varscan2
- RRP8 | c.1164G>A p.L388= | Silent (SNP) | VAF 19/43 reads (44%) | catalogued as COSV54449503; called by muse, mutect2, varscan2
- SCNN1G | c.969C>A p.S323= | Silent (SNP) | VAF 15/51 reads (29%) | catalogued as COSV55598714; called by muse, mutect2, varscan2
- SLC24A2 | c.651C>A p.L217= | Silent (SNP) | VAF 13/86 reads (15%) | catalogued as COSV53864386; called by muse, varscan2
- SLC26A5 | c.1476G>T p.V492= | Silent (SNP) | VAF 9/156 reads (6%) | called by muse, mutect2
- SLC6A2 | c.582C>T p.S194= | Silent (SNP) | VAF 23/111 reads (21%) | catalogued as rs146377944; ClinVar: likely benign; called by muse, mutect2, varscan2
- TRANK1 | c.3537A>G p.K1179= | Silent (SNP) | VAF 74/184 reads (40%) | catalogued as COSV100084539; called by muse, mutect2, varscan2
- TTBK1 | c.591C>T p.A197= | Silent (SNP) | VAF 72/164 reads (44%) | catalogued as rs143845122; called by muse, mutect2, varscan2
- TYRO3 | c.333C>T p.D111= | Silent (SNP) | VAF 17/27 reads (63%) | catalogued as rs56017003, COSV55483118; called by muse, mutect2, varscan2
- ZNF568 | c.1551C>A p.L517= | Silent (SNP) | VAF 5/65 reads (8%) | catalogued as COSV100451416; called by muse, mutect2
- GPR101 | c.-1C>T | 5'UTR (SNP) | VAF 48/141 reads (34%) | called by muse, mutect2, varscan2
- MIR29B2 | n.49A>G | RNA (SNP) | VAF 96/233 reads (41%) | catalogued as rs369475759; called by muse, mutect2, varscan2
- PLEC | chr8:143953737 C>G | 5'Flank (SNP) | VAF 35/108 reads (32%) | catalogued as COSV59633922; called by muse, mutect2, varscan2
- WASF4P | n.1010C>T | RNA (SNP) | VAF 77/214 reads (36%) | catalogued as rs782813349; called by muse, mutect2, varscan2
- ZMYM3 | c.*2C>A | 3'UTR (SNP) | VAF 30/65 reads (46%) | catalogued as COSV100078339; called by muse, mutect2, varscan2
